Gene-level copy-number profile of tumor specimen TARGET-10-PATWNL-09A from TARGET case TARGET-10-PATWNL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (633 days).
Specimen TARGET-10-PATWNL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.b6816396-ec66-55d1-a622-79eed9ecae21.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATWNL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate.
https://portal.gdc.cancer.gov/files/f7776b9d-d6f3-4af1-a4ca-82c7ce022f00

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 570; copy number 1: 754; copy number 2: 57,180; copy number 3: 810; copy number 4: 288; copy number 5: 444; copy number 6: 53; copy number 7: 150; copy number 8: 18.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes: TRGV5P, TRGV5, TRGV4.
- chr8:39,309,909–39,522,852, 3 genes: AC105185.1, ADAM5, ADAM3A.
- chr14:22,096,032–22,482,959, 28 genes (within-gene range 0–3): TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 665 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:23,767,662–25,156,314, 71 genes, copy number 5–8 (broad region; genes not listed).
- chr14:26,208,036–26,208,424, 1 gene, copy number 7: CYB5AP5.
- chr14:26,775,495–26,918,594, 5 genes, copy number 6: LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.
- chr14:29,415,856–29,500,460, 2 genes, copy number 6 (within-gene range 3–6): AL158058.2, RNU11-5P.
- chr14:29,652,809–29,657,916, 1 gene, copy number 6: AL356756.1.
- chr14:31,925,801–31,950,382, 2 genes, copy number 5 (within-gene range 4–5): AL355112.1, LINC02313.
- chr14:32,329,298–32,837,684, 1 gene, copy number 5 (within-gene range 4–5): AKAP6.
- chr14:32,879,246–34,740,833, 22 genes, copy number 5 (within-gene range 5–7): AL049781.1, NPAS3, AL161851.1, AL161851.2, EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6.
- chr14:35,121,846–35,317,474, 2 genes, copy number 5 (within-gene range 3–5): PRORP, AL121594.1.
- chr14:35,219,023–36,320,637, 30 genes, copy number 5: MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP.
- chr14:37,595,847–38,041,442, 1 gene, copy number 5 (within-gene range 3–5): TTC6.
- chr14:37,827,798–40,390,547, 32 genes, copy number 5 (within-gene range 1–5): RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1.
- chr14:41,607,570–41,904,549, 2 genes, copy number 5 (within-gene range 3–5): LRFN5, FKBP1BP1.
- chr14:43,540,883–43,596,683, 3 genes, copy number 6: KRT8P2, AL358913.1, ARHGAP16P.
- chr14:50,632,058–52,552,522, 51 genes, copy number 5–7: SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.3, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2, TRIM9, AL358334.4, AL591770.1, TMX1, SNORA70, Y_RNA, LINC00519, LINC00640, AL358332.1, LINC02310, SETP2, FRMD6-AS2, FRMD6, RNU6-1291P, AL122125.1, FRMD6-AS1, RNA5SP385, RNU6-301P, AL079307.2, OR7E105P, OR7E106P, AL079307.1, OR7E159P, AL079307.3, GNG2, AL358333.2, AL358333.3, AL358333.1, RTRAF, NID2, LINC02319, COX5AP2, AL118557.1, PTGDR, AL365475.1, PTGER2, TXNDC16.
- chr14:53,685,139–55,145,423, 22 genes, copy number 5: LINC02331, AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1, CDKN3, CNIH1, AL359792.1, GMFB, CGRRF1, SAMD4A, AL133444.1, GCH1, RNU6ATAC9P, MIR4308, FDPSP3, WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3.
- chr14:67,533,290–67,651,708, 8 genes, copy number 5: PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4.
- chr14:68,605,396–68,979,440, 12 genes, copy number 6 (within-gene range 4–6): AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3.
- chr14:69,854,131–70,032,366, 1 gene, copy number 5 (within-gene range 2–5): SMOC1.
- chr14:70,044,215–72,894,116, 54 genes, copy number 5–7 (within-gene range 4–7): SLC8A3, AL160191.1, AL160191.3, AL160191.2, ADAM21P1, AL356804.1, COX16, SYNJ2BP-COX16, RNU2-51P, SYNJ2BP, AL357153.2, ADAM21, ADAM20P1, RNU6-659P, ADAM20, AL357153.4, MED6, AL357153.3, KRT18P7, AL357153.1, RN7SL77P, TTC9, LINC01269, MAP3K9, AC004816.1, AC004816.2, AC004825.1, AC004825.2, PCNX1, AC004825.3, AC005230.1, GTF3AP2, PTTG4P, AC004817.3, AC004817.5, AC004817.2, AC004817.1, AC004817.4, AC005476.2, SIPA1L1, AC005476.1, SNORD56B, RN7SL683P, AC004974.1, AC004900.1, AC005993.1, RGS6, Y_RNA, AC004828.2, MIR7843, AC004828.1, DPF3, AL392024.1, Y_RNA.
- chr14:73,040,619–74,738,620, 73 genes, copy number 7 (broad region; genes not listed).
- chr14:76,151,916–76,501,837, 5 genes, copy number 5 (within-gene range 2–5): GPATCH2L, AC016526.2, AC016526.3, AC016526.1, ESRRB.
- chr14:81,727,780–81,743,749, 1 gene, copy number 5: LINC02311.
- chr14:81,777,016–81,777,613, 1 gene, copy number 5: RPL9P6.
- chr14:82,642,605–89,111,223, 61 genes, copy number 5–7 (broad region; genes not listed).
- chr14:89,156,743–89,157,574, 1 gene, copy number 7: AL138478.1.
- chr14:90,820,064–91,867,536, 22 genes, copy number 5 (within-gene range 4–5): LINC02321, RPS6KA5, DGLUCY, RNU7-30P, SNORA11B, GPR68, AL135818.1, AL135818.2, AL135818.3, CCDC88C, AL133153.2, AL133153.1, PPP4R3A, AL133373.2, AL133373.3, CATSPERB, POLR3GP1, NANOGP7, AL121839.1, U3, AL121839.2, TC2N.
- chr14:92,253,493–92,893,508, 8 genes, copy number 6 (within-gene range 4–6): AL133240.1, RNU6-366P, AL133240.2, SLC24A4, RIN3, LGMN, GOLGA5, LINC02833.
- chr14:93,637,179–93,929,608, 5 genes, copy number 7: AL157858.2, PRIMA1, AL132642.2, FAM181A-AS1, FAM181A.
- chr14:93,939,497–93,948,302, 2 genes, copy number 7: AL132642.1, MIR4506.
- chr14:95,181,940–95,319,908, 1 gene, copy number 5 (within-gene range 3–5): CLMN.
- chr14:95,319,483–98,514,798, 59 genes, copy number 5–8: LINC02292, SYNE3, AL133467.1, SNHG10, SCARNA13, GLRX5, LINC02318, AL133467.2, AL133467.4, TCL6, AL133467.5, AL133467.3, AL133467.6, TCL1B, TCL1A, AL139020.1, AL133167.1, TUNAR, AL137190.1, C14orf132, BDKRB2, AL355102.2, AL355102.1, CKS1BP1, AL355102.5, BDKRB1, AL355102.4, AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA, AL137786.1, RN7SKP108, AL137786.2, LINC02299, AL137786.3, VRK1, LINC00618, AL049833.3, AL049833.4, AL049833.2, AL049833.1, LINC02304, AL158800.1, LINC02325, LINC02291, AL163872.1, LINC02312, AL355097.1, LINC01550, AL163932.1, LINC02295, RN7SL714P, AL132719.1.
- chr14:98,844,896–99,535,044, 13 genes, copy number 5: AL132796.1, AL132796.3, AL132796.2, RPL3P4, AL162151.2, AL162151.3, AL162151.1, BCL11B, AL109767.1, AL132819.1, SETD3, RNU6-91P, CCNK.
- chr14:99,512,501–99,513,576, 1 gene, copy number 5: AL110504.1.
- chr14:100,657,250–101,041,445, 89 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 754. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
